Somatic mutation profile of tumor specimen TCGA-76-4927-01A (aliquot TCGA-76-4927-01A-01D-1486-08) from TCGA case TCGA-76-4927, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,193 days).
Specimen TCGA-76-4927-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a03f302c-9e72-4ea8-bfb2-757022794544.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4927-10A (Blood Derived Normal), aliquot TCGA-76-4927-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49d88609-b367-478a-a30d-b1a68be69027

The open-access MAF lists 53 somatic variants for this specimen: 36 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 15, Splice Site 2, Nonsense Mutation 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 2459/4788 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51784086; called by mutect2, varscan2
- PTEN | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 22/171 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM115947, CM971272, COSV64289566, COSV64291659; called by mutect2, varscan2
- ANKS3 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs146798732; called by muse, mutect2, varscan2
- BRCA1 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 124/372 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80356985, COSV58793323; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CACNA1S | c.812G>A p.G271D | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200305716, COSV62941116; called by muse, mutect2, varscan2
- CAMTA1 | c.3343-1G>A p.X1115_splice | Splice Site (SNP) | VAF 29/434 reads (7%) | catalogued as COSV57909528; called by muse, mutect2
- COL6A3 | c.349C>G p.Q117E | Missense Mutation (SNP) | VAF 111/317 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1559279697, COSV55095570; called by muse, mutect2, varscan2
- CTSV | c.108C>G p.H36Q | Missense Mutation (SNP) | VAF 70/234 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV52345153; called by muse, mutect2, varscan2
- DISC1 | c.2095C>T p.R699* | Nonsense Mutation (SNP) | VAF 35/150 reads (23%) | catalogued as rs190975963, COSV64091360; called by muse, mutect2, varscan2
- FAM102A | c.470C>T p.S157L (on ENST00000373095 / NM_001035254.3; = p.S15L on NM_203305.2) | Missense Mutation (SNP) | VAF 10/211 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs886683004, COSV55948341; called by muse, mutect2
- FIP1L1 | c.1019T>C p.V340A | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs1246311383, COSV60997672; called by muse, mutect2, varscan2
- GGTLC1 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 87/275 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as rs746307097, COSV53848829; called by muse, mutect2, varscan2
- GPR68 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.657); catalogued as rs778748206, COSV53176782; called by muse, mutect2, varscan2
- HDC | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201940833, COSV99983893; called by muse, mutect2, varscan2
- KITLG | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV57202583; called by muse, mutect2, varscan2
- KRTAP4-4 | c.452G>C p.C151S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.555); catalogued as rs749502434, COSV66811388; called by muse, mutect2, varscan2
- LPIN1 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV56765585; called by muse, mutect2, varscan2
- LRRC30 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.761); catalogued as COSV67301487; called by muse, mutect2, varscan2
- MAG | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 154/628 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.813); catalogued as rs201990546, COSV62702475; called by muse, mutect2, varscan2
- MUC5B | c.5786C>T p.T1929I | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV71593653; called by muse, mutect2, varscan2
- NLRP5 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.33); catalogued as rs771977909, COSV66761889; called by muse, mutect2, varscan2
- NME8 | c.198+1G>A p.X66_splice | Splice Site (SNP) | VAF 65/281 reads (23%) | catalogued as rs768239983, COSV52252036; called by muse, mutect2, varscan2
- NME8 | c.1163T>A p.L388* | Nonsense Mutation (SNP) | VAF 28/166 reads (17%) | catalogued as COSV52252047; called by muse, mutect2, varscan2
- OR52N1 | c.244A>G p.N82D | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV57693601; called by muse, mutect2, varscan2
- PACRG | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 85/279 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61308771; called by muse, mutect2, varscan2
- PCDHA5 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as COSV65353786; called by muse, varscan2
- PHKA1 | c.548T>C p.I183T | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV59807643; called by muse, mutect2, varscan2
- PKD1L1 | c.7079C>T p.P2360L | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs982895686, COSV51843093; called by muse, mutect2, varscan2
- RASAL3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV52991230; called by muse, mutect2, varscan2
- SCN1A | c.2293G>A p.V765M (on ENST00000303395 / NM_001202435.3; = p.V754M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs767074099, COSV57666152, COSV57675585; called by muse, mutect2, varscan2
- SLC6A20 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs775401748, COSV62071809; called by muse, mutect2, varscan2
- SPATA17 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs963399251, COSV65123584; called by muse, mutect2, varscan2
- TG | c.7384C>T p.L2462F | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55082532; called by muse, mutect2, varscan2
- UBAP2L | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1334396779, COSV55175956; called by muse, mutect2, varscan2
- UBXN8 | c.189A>C p.K63N | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.586); catalogued as COSV55665033; called by muse, mutect2, varscan2
- ZNF136 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.076); catalogued as rs772734603, COSV59710061; called by muse, mutect2, varscan2
- ERV3-1 | c.1185C>T p.F395= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV99275272; called by muse, mutect2
- FGD5 | c.1857C>T p.F619= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as rs771459242, COSV53243569; called by muse, mutect2, varscan2
- GJA8 | c.363C>T p.N121= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as COSV53789349, COSV99569742; called by muse, mutect2, varscan2
- INTS1 | c.3627G>A p.S1209= | Silent (SNP) | VAF 68/292 reads (23%) | catalogued as rs1157649357, COSV67177375; called by muse, varscan2
- LMBR1 | c.474G>A p.A158= | Silent (SNP) | VAF 88/384 reads (23%) | catalogued as rs201832150, COSV62221303; ClinVar: benign; called by muse, mutect2, varscan2
- MFSD2B | c.1212C>T p.H404= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as rs778812855, COSV57855200; called by muse, mutect2, varscan2
- NPAS4 | c.360C>T p.Y120= | Silent (SNP) | VAF 95/346 reads (27%) | catalogued as rs377576767, COSV60650442; called by muse, mutect2, varscan2
- PHLDB2 | c.609A>C p.S203= | Silent (SNP) | VAF 22/120 reads (18%) | catalogued as COSV67312996; called by muse, mutect2, varscan2
- PSG1 | c.1020A>T p.S340= | Silent (SNP) | VAF 73/290 reads (25%) | catalogued as COSV54952070; called by muse, mutect2, varscan2
- SLITRK4 | c.942A>T p.G314= | Silent (SNP) | VAF 11/223 reads (5%) | catalogued as COSV62024825; called by muse, mutect2
- SOWAHB | c.978C>T p.R326= | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as COSV57554753; called by muse, mutect2, varscan2
- TAC1 | c.273C>T p.G91= | Silent (SNP) | VAF 22/166 reads (13%) | catalogued as rs776999140, COSV59987783; called by muse, mutect2, varscan2
- TXNRD1 | c.1509G>A p.L503= (on ENST00000525566 / NM_001093771.3; = p.L405= on NM_003330.4) | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV61599916; called by muse, mutect2, varscan2
- USHBP1 | c.48T>G p.A16= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV53104517; called by muse, mutect2, varscan2
- ZNF470 | c.963C>T p.F321= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as COSV57968973; called by muse, mutect2, varscan2
- MIR654 | n.25G>A | RNA (SNP) | VAF 11/42 reads (26%) | catalogued as rs547817638; called by muse, mutect2
- ZNF773 | chr19:57513030 C>T | 3'Flank (SNP) | VAF 16/47 reads (34%) | catalogued as rs374374691, COSV99989138; called by muse, mutect2, varscan2
